Somatic mutation profile of tumor specimen ALCH-AEKQ-TTP1-A (aliquot ALCH-AEKQ-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEKQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-AEKQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948c87d2-04b3-4cf6-9af0-54fe7b930516.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKQ-NB1-A (Blood Derived Normal), aliquot ALCH-AEKQ-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4d98469-7063-4c4a-b61a-df6117efa3ce

The open-access MAF lists 491 somatic variants for this specimen: 312 protein-altering or splice-affecting, 114 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 264, Silent 114, Intron 24, Nonsense Mutation 20, RNA 15, Frame Shift Del 14, 5'Flank 11, Splice Site 9, 5'UTR 7, 3'UTR 6, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 109/1200 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCB11 | c.3123T>A p.Y1041* | Nonsense Mutation (SNP) | VAF 66/338 reads (20%) | catalogued as CM103539; called by muse, mutect2, varscan2
- AC004922.1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV53559078; called by muse, mutect2, varscan2
- ADAMDEC1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99836254; called by muse, mutect2, varscan2
- ADCY9 | c.1772T>C p.F591S | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV53577043; called by muse, mutect2, varscan2
- AKAP4 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 75/608 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62073830; called by muse, mutect2, varscan2
- AKAP4 | c.2004C>G p.N668K | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782020421; called by muse, varscan2
- APOA5 | c.844del p.R282Afs*15 | Frame Shift Del (DEL) | VAF 253/717 reads (35%) | catalogued as CM151061; called by mutect2, pindel, varscan2
- ARNTL2 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356276485, COSV99668280; called by muse, mutect2, varscan2
- ASXL3 | c.3562C>G p.P1188A | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV52476118, COSV52478641; called by muse, mutect2, varscan2
- ATP2C2 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370823582; called by muse, mutect2, varscan2
- BTD | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100329407; called by muse, mutect2, varscan2
- C19orf33 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 304/584 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV56651710; called by muse, mutect2, varscan2
- CA5BP1 | n.228G>C | Splice Region (SNP) | VAF 418/604 reads (69%) | catalogued as rs998633110; called by muse, mutect2, varscan2
- CASP1 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1170370473; called by muse, mutect2
- CCDC85C | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV66549988; called by muse, mutect2
- CHD2 | c.3941C>A p.A1314E | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV67714031; called by muse, mutect2, varscan2
- CHL1 | c.1955A>T p.N652I (on ENST00000397491 / NM_001253387.1; = p.N668I on NM_006614.4) | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV56608883; called by muse, mutect2, varscan2
- CHST1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.202); catalogued as rs1256615836; called by muse, mutect2, varscan2
- COL24A1 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 107/428 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100992948; called by muse, mutect2, varscan2
- DCAF4L2 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100150553; called by muse, mutect2, varscan2
- DISP1 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 423/989 reads (43%) | catalogued as COSV99452467; called by muse, mutect2, varscan2
- DPPA5 | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV64875917; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.974); catalogued as rs376721875; called by muse, mutect2, varscan2
- FAT4 | c.9695C>T p.A3232V | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs373873722; called by muse, mutect2, varscan2
- FRAS1 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369945274; called by muse, mutect2, varscan2
- GLRB | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 124/156 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs868572342; called by muse, mutect2, varscan2
- GRIN2A | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 163/904 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1555491654, COSV100410478; called by muse, mutect2, varscan2
- HAO2 | c.1035G>T p.L345F | Missense Mutation (SNP) | VAF 103/409 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV58037661; called by muse, mutect2, varscan2
- HELZ2 | c.2656G>T p.A886S (on ENST00000467148 / NM_001037335.2; = p.A317S on NM_033405.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs1569034583; called by muse, mutect2
- HOXC11 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs747007822; called by muse, mutect2, varscan2
- IFNG | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 109/672 reads (16%) | catalogued as rs767503659; called by muse, mutect2, varscan2
- IGF2BP2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 53/634 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.978); catalogued as rs780871526; called by muse, mutect2
- IGKV1-17 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 79/712 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs548975894; called by muse, varscan2
- IGKV1D-17 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 125/425 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs928824182; called by muse, mutect2, varscan2
- IMPG2 | c.2224A>G p.I742V | Missense Mutation (SNP) | VAF 183/558 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51973642; called by muse, mutect2, varscan2
- JAKMIP1 | c.1459C>A p.R487S | Missense Mutation (SNP) | VAF 115/212 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51545691; called by muse, mutect2, varscan2
- KCNJ11 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 98/122 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM074294; called by muse, mutect2, varscan2
- KCNT2 | c.1212G>T p.W404C | Missense Mutation (SNP) | VAF 69/528 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99654376; called by muse, mutect2, varscan2
- KIF2B | c.1289A>G p.Q430R | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV52135970; called by muse, mutect2, varscan2
- KIT | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 390/865 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1334133798; called by muse, varscan2
- LILRA4 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs141838994; called by muse, varscan2
- LRP1 | c.6421C>T p.Q2141* | Nonsense Mutation (SNP) | VAF 83/495 reads (17%) | catalogued as COSV54505830; called by muse, mutect2, varscan2
- LUM | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV57129102; called by muse, mutect2, varscan2
- MAPK1 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 87/148 reads (59%) | catalogued as COSV53187454; called by muse, mutect2, varscan2
- MNAT1 | c.242+1G>T p.X81_splice | Splice Site (SNP) | VAF 79/141 reads (56%) | catalogued as rs768740616; called by muse, mutect2, varscan2
- MROH6 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.732); catalogued as rs1312426834; called by muse, mutect2, varscan2
- MYOD1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000232; called by muse, mutect2, varscan2
- NLGN4X | c.2150C>A p.T717N | Missense Mutation (SNP) | VAF 96/604 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.127); catalogued as rs1398505989; called by muse, mutect2, varscan2
- NLRP12 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV60750759; called by muse, mutect2, varscan2
- OBSCN | c.14831A>C p.H4944P | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV52817589; called by muse, mutect2, varscan2
- OR10T2 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs749324831, COSV100554849; called by muse, mutect2, varscan2
- OR2L3 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 252/448 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63455742, COSV63456116; called by muse, mutect2, varscan2
- OR2M4 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2, varscan2
- OR4K1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 122/764 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53460010; called by muse, mutect2, varscan2
- OR5M11 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73141978; called by muse, varscan2
- OR6C3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 231/459 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs866375503, COSV65570631; called by muse, mutect2, varscan2
- PBX2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.219); catalogued as rs200483918; called by muse, mutect2, varscan2
- PCDHGA6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 127/151 reads (84%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV54020507; called by muse, mutect2, varscan2
- PCDHGA6 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 82/109 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); catalogued as rs1385892757; called by mutect2, varscan2
- PDGFD | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 225/630 reads (36%) | catalogued as rs1373391412; called by muse, mutect2, varscan2
- PEAR1 | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.428); catalogued as COSV52772720; called by muse, mutect2, varscan2
- POLD4 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750048961, COSV56744535; called by muse, mutect2, varscan2
- POMT2 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 252/498 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs911038793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP2R2B | c.1190del p.G397Afs*31 (on ENST00000394409; = p.G463Afs*31 on NM_181674.2) | Frame Shift Del (DEL) | VAF 300/608 reads (49%) | catalogued as rs767808084; called by pindel, varscan2
- PTPRN2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 190/387 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV67059806; called by muse, mutect2, varscan2
- PTX4 | c.650C>G p.S217C (on ENST00000447419 / NM_001328608.2; = p.S212C on NM_001013658.1) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53517979; called by muse, mutect2, varscan2
- RNASEL | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 193/876 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs375872977; called by muse, mutect2, varscan2
- RNGTT | c.1282A>T p.N428Y | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99667447; called by muse, varscan2
- SBSN | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 265/505 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV71733350; called by muse, mutect2, varscan2
- SCN4B | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 365/828 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140348243, CM109585; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHB | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as rs1412375956; called by muse, mutect2, varscan2
- SLC17A3 | c.759+1G>T p.X253_splice | Splice Site (SNP) | VAF 268/533 reads (50%) | catalogued as COSV57760036; called by muse, mutect2, varscan2
- SPATA31A6 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 300/1380 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs745969363; called by muse, mutect2, varscan2
- SPTBN1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61689230; called by muse, mutect2, varscan2
- SSBP3 | c.420del p.S141Afs*3 | Frame Shift Del (DEL) | VAF 35/164 reads (21%) | catalogued as COSV58887464; called by mutect2, pindel, varscan2
- SYNE1 | c.8539G>A p.D2847N (on ENST00000367255 / NM_182961.4; = p.D2854N on NM_033071.3) | Missense Mutation (SNP) | VAF 167/676 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55133582; called by muse, mutect2, varscan2
- TMEM150B | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 164/314 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs1210077170; called by muse, mutect2, varscan2
- TMEM82 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs749109111; called by muse, mutect2, varscan2
- TNK2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 211/506 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV100361566; called by muse, mutect2, varscan2
- TP53 | c.929del p.N310Tfs*35 | Frame Shift Del (DEL) | VAF 229/362 reads (63%) | catalogued as COSV52772317; called by mutect2, pindel, varscan2
- TRERF1 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 197/386 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as rs564334935; called by muse, mutect2, varscan2
- TRIB3 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 351/641 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764336159, COSV53932394, COSV99423645; called by muse, mutect2, varscan2
- TTN | c.31157A>T p.K10386M (on ENST00000591111; = p.K9459M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/204 reads (35%) | PolyPhen probably damaging (0.997); catalogued as COSV60052796; called by muse, mutect2, varscan2
- TTN | c.24974C>A p.P8325Q (on ENST00000591111; = p.P7398Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | PolyPhen probably damaging (0.945); catalogued as COSV100592539; called by muse, mutect2, varscan2
- USP13 | c.1451G>A p.C484Y | Missense Mutation (SNP) | VAF 115/1698 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.916); catalogued as COSV99831853; called by muse, mutect2
- VN1R4 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1212058729; called by muse, mutect2, varscan2
- ZBTB7A | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755220452, COSV59329695; called by muse, mutect2, varscan2
- ZNF133 | c.1574G>T p.R525L (on ENST00000316358 / NM_001352454.2; = p.R524L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.198); catalogued as COSV60366386; called by muse, mutect2, varscan2
- ZNF248 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 297/390 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV61997190; called by muse, mutect2, varscan2
- ZNF454 | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 118/143 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60766568; called by muse, mutect2, varscan2
- ZNF570 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs756858149; called by muse, mutect2
- ZNF804A | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 236/446 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56447299, COSV56450959; called by muse, mutect2, varscan2
- A2ML1 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 288/600 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ACOT9 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 311/456 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ADAM20 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 164/301 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ADGRE3 | c.1278G>T p.L426F | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRL3 | c.1154G>T p.C385F (on ENST00000506720 / NM_001322402.2; = p.C317F on NM_015236.6) | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFDN | c.5472G>T p.K1824N (on ENST00000447894 / NM_001366320.1; = p.K1743N on NM_001207008.1) | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKR1D1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 258/545 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO4 | c.733C>A p.H245N (on ENST00000392977 / NM_001286615.2; = p.H210N on NM_178826.4) | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ANO8 | c.245G>C p.W82S | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP1 | c.634A>T p.K212* | Nonsense Mutation (SNP) | VAF 36/279 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.3078G>T p.L1026F | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID2 | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ASPH | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AVPR1B | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GNT2 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 131/865 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS7 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 368/490 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- BIRC6 | c.9340A>C p.S3114R | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BLCAP | c.2_12del p.M1_?4 | Frame Shift Del (DEL) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- BRCA2 | c.5515G>T p.V1839L | Missense Mutation (SNP) | VAF 242/270 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNA1C | c.5391del p.L1798Cfs*54 (on ENST00000399634 / NM_001167625.1; = p.L1798Cfs*42 on NM_000719.7) | Frame Shift Del (DEL) | VAF 45/133 reads (34%) | called by mutect2, varscan2
- CACNA1F | c.5690G>T p.S1897I | Missense Mutation (SNP) | VAF 92/608 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CAD | c.3793C>A p.Q1265K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CADM3 | c.334A>T p.I112F (on ENST00000368125 / NM_001127173.3; = p.I146F on NM_021189.5) | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CAMSAP1 | c.4255G>A p.G1419S | Missense Mutation (SNP) | VAF 166/216 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC115 | c.430+8G>A | Splice Region (SNP) | VAF 284/704 reads (40%) | called by muse, mutect2, varscan2
- CCDC141 | c.3800C>A p.P1267Q | Missense Mutation (SNP) | VAF 105/476 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CCDC22 | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1B | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 155/520 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CD22 | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 146/257 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD300LD | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 387/479 reads (81%) | called by muse, mutect2, varscan2
- CELF5 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.5072T>C p.I1691T | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.052); called by muse, varscan2
- CHRM1 | c.320T>A p.V107E | Missense Mutation (SNP) | VAF 164/385 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLASP1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 103/508 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC4F | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CLIP2 | c.2372A>T p.E791V | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- COBL | c.2820C>A p.H940Q | Missense Mutation (SNP) | VAF 124/218 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL6A3 | c.5330G>C p.G1777A | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.7027C>T p.P2343S (on ENST00000312481; = p.P2339S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/519 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CPNE4 | c.180+1G>C p.X60_splice | Splice Site (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- CPS1 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAAM2 | c.2763C>G p.S921R (on ENST00000274867 / NM_001201427.2; = p.S920R on NM_015345.3) | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DCAF8L1 | c.8del p.H3Pfs*12 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- DCC | c.1711G>T p.G571* | Nonsense Mutation (SNP) | VAF 236/843 reads (28%) | called by muse, mutect2, varscan2
- DCHS1 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.514); called by muse, mutect2
- DCPS | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DDIT4 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DENND2B | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 265/340 reads (78%) | called by muse, mutect2, varscan2
- DHPS | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DHX15 | c.2102T>G p.V701G | Missense Mutation (SNP) | VAF 266/373 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- DMD | c.4534C>A p.L1512M | Missense Mutation (SNP) | VAF 129/760 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DNAH14 | c.1042T>G p.S348A (on ENST00000445597; = p.S329A on NM_001145154.3) | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DOCK10 | c.6073G>C p.E2025Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DYNC2H1 | c.7338G>T p.L2446F | Missense Mutation (SNP) | VAF 170/487 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ECSCR | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 200/268 reads (75%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EEF1A2 | c.509T>A p.I170N | Missense Mutation (SNP) | VAF 335/683 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 294/804 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EHBP1 | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 212/767 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- EML6 | c.4867G>T p.G1623C | Missense Mutation (SNP) | VAF 140/445 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ENO2 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ENTHD1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESPL1 | c.4447G>C p.E1483Q | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EZH1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- F13A1 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 638/969 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FRMPD1 | c.1084A>T p.M362L | Missense Mutation (SNP) | VAF 275/569 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FSIP2 | c.14302G>T p.V4768F | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FUT10 | c.1009A>G p.I337V | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- GALNT14 | c.992T>G p.V331G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJD2 | c.557A>T p.K186I | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GOLGA3 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 371/679 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GOLGA6L2 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2307G>T p.E769D | Missense Mutation (SNP) | VAF 70/795 reads (9%) | SIFT deleterious (0.03); called by muse, varscan2
- GRAMD4 | c.457A>C p.N153H | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRID2 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 298/476 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HELQ | c.3199-2A>T p.X1067_splice | Splice Site (SNP) | VAF 202/772 reads (26%) | called by muse, mutect2, varscan2
- HELZ2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 136/431 reads (32%) | called by muse, mutect2, varscan2
- HNRNPK | c.255_257+11del p.X85_splice | Splice Site (DEL) | VAF 77/324 reads (24%) | called by mutect2, pindel, varscan2
- HOXC11 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 487/960 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3D | c.743C>T p.A248V (on ENST00000382489 / NM_001163646.2; = p.A75V on NM_182537.3) | Missense Mutation (SNP) | VAF 210/844 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFI44L | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IGKV2D-30 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 284/746 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- IGSF10 | c.2294del p.K765Rfs*13 | Frame Shift Del (DEL) | VAF 405/971 reads (42%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.3790C>G p.P1264A | Missense Mutation (SNP) | VAF 113/167 reads (68%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- IQUB | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 152/408 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCND2 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ3 | c.1308A>T p.K436N | Missense Mutation (SNP) | VAF 121/759 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF2C | c.1510A>C p.S504R | Missense Mutation (SNP) | VAF 167/551 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- KIF6 | c.1852G>T p.V618L | Missense Mutation (SNP) | VAF 91/499 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KIR2DL4 | c.985T>G p.S329A (on ENST00000396284; = p.S255A on NM_001080770.2) | Missense Mutation (SNP) | VAF 361/949 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIRREL2 | c.1842C>G p.S614R | Missense Mutation (SNP) | VAF 167/377 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIRREL2 | c.2077T>A p.Y693N | Missense Mutation (SNP) | VAF 109/429 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIRREL3 | c.1806G>A p.M602I | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KLHL12 | c.1338C>G p.Y446* | Nonsense Mutation (SNP) | VAF 175/442 reads (40%) | called by muse, mutect2, varscan2
- KMT2D | c.9342_9354del p.L3115Sfs*23 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | called by mutect2, pindel, varscan2
- KRTAP13-4 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 236/294 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- L1TD1 | c.234del p.A79Qfs*3 | Frame Shift Del (DEL) | VAF 139/312 reads (45%) | called by mutect2, pindel, varscan2
- LCP2 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 194/255 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LDLRAD2 | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LEPROT | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LILRB2 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 128/463 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LITAF | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2
- LRFN2 | c.1727A>T p.Y576F | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- LRRC71 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 139/302 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEB3 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 299/417 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDN1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 417/802 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MGAT4C | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 223/514 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIB1 | c.36del p.V14Lfs*5 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | called by pindel, varscan2
- MKLN1 | c.16del p.A6Lfs*31 | Frame Shift Del (DEL) | VAF 40/149 reads (27%) | called by mutect2, pindel, varscan2
- MON2 | c.3451C>T p.Q1151* | Nonsense Mutation (SNP) | VAF 92/383 reads (24%) | called by muse, mutect2, varscan2
- MROH7 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 223/437 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MRPS9 | c.302A>C p.Q101P | Missense Mutation (SNP) | VAF 238/576 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- MSX2 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 306/428 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.19493C>A p.S6498* | Nonsense Mutation (SNP) | VAF 77/146 reads (53%) | called by muse, mutect2, varscan2
- MUC6 | c.1134C>G p.T378= | Splice Region (SNP) | VAF 99/139 reads (71%) | called by muse, mutect2, varscan2
- MYH6 | c.4096G>C p.A1366P | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYO16 | c.3294C>G p.F1098L | Missense Mutation (SNP) | VAF 169/202 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5B | c.2480G>T p.R827M | Missense Mutation (SNP) | VAF 430/832 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NAT8 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 172/564 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NCAN | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NFIX | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- NGB | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NLRP3 | c.2395G>C p.V799L | Missense Mutation (SNP) | VAF 202/715 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NLRP5 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 167/284 reads (59%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOP14 | c.2426_2435dup p.F813Gfs*29 | Frame Shift Ins (INS) | VAF 52/292 reads (18%) | called by mutect2, varscan2
- NOSTRIN | c.27+1G>C p.X9_splice | Splice Site (SNP) | VAF 259/519 reads (50%) | called by muse, mutect2, varscan2
- NPAT | c.1449A>G p.I483M | Missense Mutation (SNP) | VAF 260/629 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPC1 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NR0B1 | c.66A>T p.Q22H | Missense Mutation (SNP) | VAF 130/170 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NRK | c.1037T>C p.F346S | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NT5C1A | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NUP210L | c.879A>G p.I293M | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OR2B3 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 77/157 reads (49%) | called by muse, mutect2, varscan2
- OR2M5 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR2Z1 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 117/408 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR2Z1 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 118/407 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5M8 | c.715A>C p.T239P | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR6B3 | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8S1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 169/479 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- P2RY2 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 214/524 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PARP10 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PDE3A | c.1815T>A p.S605R | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHGDH | c.411+1G>T p.X137_splice | Splice Site (SNP) | VAF 220/741 reads (30%) | called by muse, mutect2, varscan2
- PIK3C3 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- PLXNA3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 318/678 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PPP1CB | c.515A>C p.H172P | Missense Mutation (SNP) | VAF 117/584 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP2R3B | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PRAMEF17 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 152/583 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PRAMEF17 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 154/583 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PRKAB1 | c.260dup p.G88Rfs*15 | Frame Shift Ins (INS) | VAF 93/384 reads (24%) | called by mutect2, pindel, varscan2
- PRPS2 | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTCHD4 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTPRK | c.3635C>G p.P1212R (on ENST00000368215 / NM_001291984.2; = p.P1213R on NM_002844.4) | Missense Mutation (SNP) | VAF 22/489 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- PTPRQ | c.2167G>A p.E723K (on ENST00000616559; = p.E681K on NM_001145026.2) | Missense Mutation (SNP) | VAF 251/752 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- RBM47 | c.1110C>A p.D370E | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- RBM47 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2
- RGPD2 | c.3809T>A p.V1270E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- RHOBTB1 | c.483-2A>C p.X161_splice | Splice Site (SNP) | VAF 77/97 reads (79%) | called by muse, varscan2
- RHPN1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 116/224 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMBP2 | c.840C>A p.N280K | Missense Mutation (SNP) | VAF 289/549 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RIMS1 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 137/261 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPH3A | c.884G>T p.G295V (on ENST00000389385 / NM_001143854.2; = p.G291V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/435 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- RXFP1 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 162/243 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SCEL | c.1557C>G p.I519M (on ENST00000349847 / NM_144777.3; = p.I499M on NM_003843.4) | Missense Mutation (SNP) | VAF 125/195 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- SEL1L2 | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 301/820 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEMA5A | c.2895G>C p.E965D | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB8 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 218/433 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SHROOM4 | c.2982_2984delinsAA p.S994Rfs*38 | Frame Shift Del (DEL) | VAF 107/334 reads (32%) | called by pindel, varscan2*
- SLC35F2 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35G2 | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLC37A3 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A3 | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 189/492 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- SLC9A6 | c.1177A>T p.I393F | Missense Mutation (SNP) | VAF 250/337 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLCO5A1 | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SOGA3 | c.1862A>T p.D621V | Missense Mutation (SNP) | VAF 105/447 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SORL1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 65/317 reads (21%) | called by muse, mutect2, varscan2
- SPINT2 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 424/813 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SPO11 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.034); called by muse, varscan2
- SPTBN4 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- SSTR4 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 212/247 reads (86%) | PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STAB2 | c.2901G>T p.L967F | Missense Mutation (SNP) | VAF 199/399 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TAAR2 | c.351G>T p.K117N (on ENST00000367931 / NM_001033080.1; = p.K72N on NM_014626.3) | Missense Mutation (SNP) | VAF 212/449 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL2 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 75/289 reads (26%) | called by muse, mutect2, varscan2
- TDRD6 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.3181A>T p.K1061* (on ENST00000256246; = p.K1444* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- TFE3 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.1842G>T p.Q614H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TNN | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 397/841 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TPH2 | c.879C>G p.Y293* | Nonsense Mutation (SNP) | VAF 466/943 reads (49%) | called by muse, mutect2, varscan2
- TPO | c.1517C>A p.A506D | Missense Mutation (SNP) | VAF 130/394 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRIM55 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 124/519 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSNAXIP1 | c.484_485del p.K162Efs*2 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- TTN | c.15812G>C p.S5271T (on ENST00000591111; = p.S4344T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/337 reads (17%) | PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTN | c.11755C>A p.P3919T (on ENST00000591111; = p.P3873T on NM_003319.4) | Missense Mutation (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- UBE3A | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- UNC13A | c.3315T>A p.H1105Q | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- UNC80 | c.9232C>G p.Q3078E | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- USP21 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 180/475 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- VCP | c.2004G>T p.K668N | Missense Mutation (SNP) | VAF 122/463 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- VCP | c.2002A>T p.K668* | Nonsense Mutation (SNP) | VAF 122/470 reads (26%) | called by muse, mutect2
- VWF | c.695C>G p.S232W | Missense Mutation (SNP) | VAF 84/701 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XKR4 | c.1386T>A p.F462L | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YEATS2 | c.3635A>T p.N1212I | Missense Mutation (SNP) | VAF 499/1341 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- YIPF5 | c.587G>C p.S196T | Missense Mutation (SNP) | VAF 150/197 reads (76%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBBX | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 146/508 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZBTB20 | c.773A>G p.E258G (on ENST00000474710 / NM_001164342.2; = p.E185G on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZCCHC8 | c.1737T>G p.D579E | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 132/237 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDHHC17 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 139/466 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZMAT4 | c.630A>G p.I210M | Missense Mutation (SNP) | VAF 218/437 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ZNF175 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 90/434 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF792 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF804A | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 105/163 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF99 | c.2427A>G p.I809M | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZXDC | c.1348A>G p.K450E | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- AAMP | c.126C>T p.D42= | Silent (SNP) | VAF 96/415 reads (23%) | called by muse, mutect2, varscan2
- ADAM19 | c.2490G>A p.S830= | Silent (SNP) | VAF 116/154 reads (75%) | catalogued as rs764968777, COSV57427459; called by muse, mutect2, varscan2
- ADGRG4 | c.2625A>C p.A875= | Silent (SNP) | VAF 128/174 reads (74%) | called by muse, mutect2, varscan2
- ANKRD26 | c.2733G>A p.S911= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs996859183, COSV101063018; called by muse, mutect2, varscan2
- ANKRD30B | c.394C>T p.L132= | Silent (SNP) | VAF 158/296 reads (53%) | catalogued as rs747990388; called by muse, mutect2, varscan2
- ANKRD30B | c.945C>A p.A315= | Silent (SNP) | VAF 340/667 reads (51%) | catalogued as COSV62811748, COSV62816026; called by muse, mutect2, varscan2
- ARID1B | c.6555G>T p.A2185= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99273031; called by muse, mutect2, varscan2
- ARL6IP4 | c.966G>T p.P322= (on ENST00000315580 / NM_018694.3; = p.P303= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- BAZ2A | c.1926G>A p.P642= | Silent (SNP) | VAF 342/646 reads (53%) | catalogued as rs562319546; called by muse, mutect2, varscan2
- BBS10 | c.324G>A p.L108= | Silent (SNP) | VAF 200/373 reads (54%) | called by muse, mutect2, varscan2
- BTD | c.1332G>T p.G444= | Silent (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- CACNA1C | c.3072C>T p.V1024= | Silent (SNP) | VAF 209/603 reads (35%) | catalogued as rs566310000, COSV59738474; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1F | c.5598C>T p.G1866= | Silent (SNP) | VAF 48/277 reads (17%) | called by muse, varscan2
- CACNA1S | c.432C>A p.V144= | Silent (SNP) | VAF 221/586 reads (38%) | called by muse, mutect2, varscan2
- CADM2 | c.249C>A p.S83= (on ENST00000407528 / NM_001167674.2; = p.S85= on NM_153184.4) | Silent (SNP) | VAF 140/190 reads (74%) | called by muse, mutect2, varscan2
- CDH2 | c.270G>C p.V90= | Silent (SNP) | VAF 173/717 reads (24%) | called by muse, mutect2, varscan2
- CFAP54 | c.4926C>T p.A1642= | Silent (SNP) | VAF 355/702 reads (51%) | called by muse, varscan2
- CLIP2 | c.2541G>A p.E847= | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as rs1554314833; called by muse, mutect2, varscan2
- CLK3 | c.753C>T p.T251= (on ENST00000395066 / NM_001130028.1; = p.T103= on NM_003992.4) | Silent (SNP) | VAF 85/217 reads (39%) | catalogued as rs1218322061; called by muse, mutect2, varscan2
- CNTNAP2 | c.2196C>T p.I732= | Silent (SNP) | VAF 146/549 reads (27%) | catalogued as rs769830314, COSV62192120, COSV62206510; called by muse, mutect2, varscan2
- CRACD | c.1782C>A p.T594= | Silent (SNP) | VAF 98/218 reads (45%) | called by muse, mutect2, varscan2
- CTNND2 | c.18G>T p.P6= | Silent (SNP) | VAF 116/178 reads (65%) | called by muse, mutect2, varscan2
- DMRTB1 | c.789C>T p.Y263= | Silent (SNP) | VAF 154/407 reads (38%) | catalogued as COSV65113299; called by mutect2, varscan2
- DNAH5 | c.5127A>G p.K1709= | Silent (SNP) | VAF 407/891 reads (46%) | called by muse, mutect2, varscan2
- DNAH9 | c.11322G>A p.L3774= | Silent (SNP) | VAF 52/272 reads (19%) | called by muse, mutect2, varscan2
- DPYSL2 | c.1167C>G p.A389= | Silent (SNP) | VAF 81/209 reads (39%) | called by muse, mutect2, varscan2
- EGLN3 | c.630C>A p.V210= | Silent (SNP) | VAF 92/412 reads (22%) | called by muse, mutect2, varscan2
- EPHB1 | c.165C>A p.I55= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- FKBP15 | c.738G>T p.L246= | Silent (SNP) | VAF 67/94 reads (71%) | called by muse, varscan2
- FNDC1 | c.3294G>T p.A1098= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as rs1163677489; called by muse, mutect2, varscan2
- FOXG1 | c.1317G>C p.A439= | Silent (SNP) | VAF 191/352 reads (54%) | catalogued as COSV57399276; called by muse, mutect2, varscan2
- FSIP2 | c.2758C>T p.L920= | Silent (SNP) | VAF 162/278 reads (58%) | catalogued as rs1417651431; called by muse, varscan2
- FUT9 | c.141G>A p.V47= | Silent (SNP) | VAF 64/277 reads (23%) | called by muse, mutect2, varscan2
- GLRA3 | c.285C>A p.I95= | Silent (SNP) | VAF 101/136 reads (74%) | called by muse, mutect2, varscan2
- GNA13 | c.930A>G p.L310= | Silent (SNP) | VAF 266/309 reads (86%) | catalogued as rs941409424; called by muse, mutect2, varscan2
- GPIHBP1 | c.438C>G p.V146= | Silent (SNP) | VAF 204/400 reads (51%) | catalogued as rs776022117; called by muse, mutect2, varscan2
- GPR89A | c.957C>G p.V319= | Silent (SNP) | VAF 104/318 reads (33%) | called by muse, mutect2, varscan2
- GRIP1 | c.981G>A p.Q327= | Silent (SNP) | VAF 308/651 reads (47%) | called by muse, mutect2, varscan2
- GRM8 | c.1884G>T p.G628= | Silent (SNP) | VAF 121/412 reads (29%) | catalogued as COSV58841588; called by muse, mutect2, varscan2
- HAUS7 | c.282C>T p.F94= | Silent (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- HOXA5 | c.321C>A p.A107= | Silent (SNP) | VAF 136/267 reads (51%) | called by muse, mutect2, varscan2
- HRC | c.66C>A p.L22= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as COSV53255188; called by muse, mutect2, varscan2
- HRNR | c.7842T>A p.S2614= | Silent (SNP) | VAF 14/109 reads (13%) | called by mutect2, varscan2
- HSPA6 | c.777G>A p.K259= | Silent (SNP) | VAF 80/415 reads (19%) | called by muse, mutect2, varscan2
- HTR1E | c.936G>A p.L312= | Silent (SNP) | VAF 104/202 reads (51%) | catalogued as rs113308093; called by muse, mutect2, varscan2
- IGLV3-9 | c.171G>A p.K57= | Silent (SNP) | VAF 319/677 reads (47%) | catalogued as rs781175411; called by muse, mutect2, varscan2
- INSYN2B | c.306T>C p.S102= | Silent (SNP) | VAF 80/105 reads (76%) | called by muse, mutect2, varscan2
- IQGAP1 | c.4935C>T p.L1645= | Silent (SNP) | VAF 59/204 reads (29%) | called by muse, mutect2, varscan2
- KBTBD13 | c.462C>A p.P154= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- KLHL30 | c.114G>T p.L38= | Silent (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.390G>A p.L130= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- LMO7 | c.4779C>T p.V1593= (on ENST00000357063; = p.V1274= on NM_005358.5) | Silent (SNP) | VAF 65/80 reads (81%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5460C>A p.T1820= (on ENST00000642948; = p.T1758= on NM_144612.7) | Silent (SNP) | VAF 87/366 reads (24%) | called by muse, mutect2, varscan2
- LRRC63 | c.465G>A p.K155= | Silent (SNP) | VAF 74/339 reads (22%) | called by muse, mutect2, varscan2
- LRRC74B | c.663C>G p.L221= | Silent (SNP) | VAF 157/355 reads (44%) | called by muse, mutect2, varscan2
- MAGEB18 | c.420G>A p.K140= | Silent (SNP) | VAF 450/640 reads (70%) | catalogued as COSV57464440; called by muse, mutect2, varscan2
- MBD5 | c.3765A>T p.P1255= | Silent (SNP) | VAF 205/544 reads (38%) | catalogued as COSV101290096; called by muse, mutect2, varscan2
- MSX2 | c.577C>A p.R193= | Silent (SNP) | VAF 299/415 reads (72%) | called by mutect2, varscan2
- MYH4 | c.3388C>A p.R1130= | Silent (SNP) | VAF 278/346 reads (80%) | catalogued as rs772548795; called by muse, mutect2, varscan2
- MYH8 | c.639C>A p.G213= | Silent (SNP) | VAF 545/700 reads (78%) | catalogued as rs758456274; called by muse, mutect2, varscan2
- MYL2 | c.15A>G p.K5= | Silent (SNP) | VAF 144/402 reads (36%) | called by muse, mutect2, varscan2
- NEDD1 | c.531A>T p.L177= | Silent (SNP) | VAF 298/586 reads (51%) | called by muse, mutect2, varscan2
- NEO1 | c.4104G>A p.P1368= | Silent (SNP) | VAF 115/320 reads (36%) | catalogued as rs200012151; called by muse, mutect2, varscan2
- NOTCH1 | c.2004G>A p.P668= | Silent (SNP) | VAF 98/282 reads (35%) | catalogued as rs746470497; called by muse, mutect2, varscan2
- NR2E1 | c.693A>G p.A231= | Silent (SNP) | VAF 377/731 reads (52%) | called by muse, mutect2, varscan2
- OR10H1 | c.249C>A p.A83= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV58470691; called by muse, mutect2, varscan2
- OR12D3 | c.222G>C p.V74= | Silent (SNP) | VAF 110/203 reads (54%) | catalogued as COSV65826940; called by muse, mutect2, varscan2
- OR1L4 | c.630C>G p.T210= | Silent (SNP) | VAF 211/593 reads (36%) | called by muse, mutect2, varscan2
- OR2A25 | c.264C>A p.A88= | Silent (SNP) | VAF 176/376 reads (47%) | called by muse, mutect2, varscan2
- OR2H1 | c.657T>A p.T219= | Silent (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- OR51E2 | c.468C>T p.F156= | Silent (SNP) | VAF 205/278 reads (74%) | catalogued as rs1564885145, COSV67807091; called by muse, mutect2, varscan2
- PCDHA12 | c.2184C>T p.T728= | Silent (SNP) | VAF 188/239 reads (79%) | catalogued as rs782196097, COSV56482972; called by muse, mutect2, varscan2
- PIK3C2G | c.729G>T p.T243= | Silent (SNP) | VAF 137/306 reads (45%) | called by muse, mutect2, varscan2
- PKD1L1 | c.3747T>C p.F1249= | Silent (SNP) | VAF 130/253 reads (51%) | called by muse, mutect2, varscan2
- PLCB3 | c.3663G>A p.S1221= | Silent (SNP) | VAF 59/308 reads (19%) | catalogued as rs759156326; called by muse, mutect2, varscan2
- POM121L12 | c.771C>A p.V257= | Silent (SNP) | VAF 96/201 reads (48%) | called by muse, mutect2, varscan2
- PPP1R8 | c.930A>G p.A310= (on ENST00000311772 / NM_014110.5; = p.A86= on NM_002713.4) | Silent (SNP) | VAF 57/272 reads (21%) | called by muse, mutect2, varscan2
- PURG | c.957A>T p.T319= | Silent (SNP) | VAF 82/252 reads (33%) | called by muse, mutect2, varscan2
- PXDNL | c.4284G>T p.V1428= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs1563355642; called by muse, mutect2, varscan2
- RADIL | c.1101G>T p.R367= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2
- RBBP8 | c.2394G>T p.V798= | Silent (SNP) | VAF 212/797 reads (27%) | called by muse, mutect2, varscan2
- RHEX | c.486T>A p.S162= | Silent (SNP) | VAF 192/511 reads (38%) | called by muse, mutect2, varscan2
- RRP1B | c.2157G>A p.Q719= | Silent (SNP) | VAF 23/662 reads (3%) | called by muse, mutect2
- RXFP3 | c.1221C>A p.I407= | Silent (SNP) | VAF 224/367 reads (61%) | catalogued as COSV57504408, COSV57508152; called by muse, mutect2, varscan2
- SERPINB9 | c.849G>C p.V283= | Silent (SNP) | VAF 52/527 reads (10%) | called by muse, mutect2, varscan2
- SHISA6 | c.1113C>A p.V371= (on ENST00000409168 / NM_001173461.1; = p.V422= on NM_207386.4) | Silent (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- SIRT7 | c.1200G>T p.T400= | Silent (SNP) | VAF 341/418 reads (82%) | catalogued as rs374568755; called by muse, mutect2, varscan2
- SLC18B1 | c.870A>G p.L290= | Silent (SNP) | VAF 267/506 reads (53%) | catalogued as rs149512313, COSV51594527; called by muse, mutect2, varscan2
- SLC26A7 | c.573G>T p.V191= | Silent (SNP) | VAF 76/303 reads (25%) | called by muse, mutect2, varscan2
- SLC9A9 | c.63G>C p.A21= | Silent (SNP) | VAF 190/610 reads (31%) | called by muse, mutect2, varscan2
- SORCS1 | c.768G>A p.L256= | Silent (SNP) | VAF 230/280 reads (82%) | catalogued as rs775365753, COSV53853967; called by muse, mutect2, varscan2
- SPATA3 | c.225C>A p.P75= | Silent (SNP) | VAF 138/341 reads (40%) | catalogued as COSV101330919; called by muse, mutect2, varscan2
- SPATA31A1 | c.3552A>G p.P1184= | Silent (SNP) | VAF 239/1496 reads (16%) | called by muse, mutect2, varscan2
- STARD8 | c.1401G>A p.L467= | Silent (SNP) | VAF 100/132 reads (76%) | catalogued as rs1169159897; called by muse, mutect2, varscan2
- STK11 | c.57G>C p.S19= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs748698151; ClinVar: likely benign; called by muse, mutect2, varscan2
- STON1 | c.144G>A p.R48= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs147058798; called by muse, mutect2, varscan2
- TBX10 | c.1101G>T p.G367= | Silent (SNP) | VAF 64/260 reads (25%) | catalogued as rs748480424; called by muse, mutect2, varscan2
- TCP11 | c.183G>A p.K61= (on ENST00000512012; = p.K56= on NM_001261817.2) | Silent (SNP) | VAF 72/411 reads (18%) | catalogued as rs763226033; called by muse, mutect2, varscan2
- TIGAR | c.138G>T p.L46= | Silent (SNP) | VAF 110/348 reads (32%) | called by muse, mutect2, varscan2
- TMEM67 | c.2298C>T p.F766= | Silent (SNP) | VAF 85/378 reads (22%) | catalogued as rs372104198; called by muse, mutect2, varscan2
- TPH2 | c.300G>A p.R100= | Silent (SNP) | VAF 326/642 reads (51%) | catalogued as rs767461365, COSV61592724, COSV61593860; called by muse, mutect2, varscan2
- TRIM48 | c.39C>G p.T13= | Silent (SNP) | VAF 208/593 reads (35%) | called by muse, mutect2, varscan2
- TSGA13 | c.822C>A p.I274= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV58406515; called by muse, mutect2, varscan2
- TXLNB | c.645G>A p.E215= | Silent (SNP) | VAF 72/291 reads (25%) | called by muse, mutect2, varscan2
- UBA1 | c.1134G>C p.L378= | Silent (SNP) | VAF 366/524 reads (70%) | called by muse, mutect2, varscan2
- ULBP3 | c.42G>C p.A14= | Silent (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- USHBP1 | c.612C>T p.I204= | Silent (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- USP35 | c.201G>A p.V67= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- UTS2R | c.705C>A p.A235= | Silent (SNP) | VAF 110/123 reads (89%) | called by muse, mutect2, varscan2
- WDR7 | c.4365G>T p.A1455= | Silent (SNP) | VAF 200/368 reads (54%) | catalogued as rs547450912, COSV54349017, COSV54360228; called by muse, mutect2, varscan2
- ZIC1 | c.273C>T p.S91= | Silent (SNP) | VAF 22/245 reads (9%) | catalogued as rs1182989093, COSV99292565; called by muse, mutect2
- ZNF624 | c.102C>A p.T34= | Silent (SNP) | VAF 222/440 reads (50%) | called by muse, mutect2, varscan2
- ZNF676 | c.171G>A p.E57= (on ENST00000650058; = p.E25= on NM_001001411.3) | Silent (SNP) | VAF 47/153 reads (31%) | called by muse, mutect2, varscan2
- ZNF775 | c.1008G>C p.P336= | Silent (SNP) | VAF 74/288 reads (26%) | catalogued as COSV100301394; called by muse, mutect2, varscan2
- AC107023.1 | n.26-7108G>T | Intron (SNP) | VAF 176/571 reads (31%) | called by muse, mutect2, varscan2
- AC136759.1 | n.683G>T | RNA (SNP) | VAF 193/463 reads (42%) | called by muse, mutect2, varscan2
- AHSA2P | n.1541G>C | RNA (SNP) | VAF 85/485 reads (18%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821605 T>A | 3'Flank (SNP) | VAF 341/472 reads (72%) | called by muse, mutect2, varscan2
- ALG13 | c.-8C>T | 5'UTR (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.976T>C | RNA (SNP) | VAF 20/67 reads (30%) | catalogued as rs767762706; called by muse, mutect2, varscan2
- AP002008.2 | n.1423G>T | RNA (SNP) | VAF 119/268 reads (44%) | catalogued as rs754032227; called by muse, mutect2, varscan2
- AP004607.5 | n.168C>A | RNA (SNP) | VAF 48/544 reads (9%) | called by muse, varscan2
- ASCC3 | c.801+21T>C | Intron (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- ATIC | c.*50C>T | 3'UTR (SNP) | VAF 29/454 reads (6%) | catalogued as rs372850993; called by muse, mutect2
- B3GALT5-AS1 | n.657C>T | RNA (SNP) | VAF 396/484 reads (82%) | catalogued as COSV61594595; called by muse, mutect2, varscan2
- BAIAP2 | c.54+1616del | Intron (DEL) | VAF 65/596 reads (11%) | called by mutect2, pindel, varscan2
- C2CD6 | c.1581+3172A>C | Intron (SNP) | VAF 45/179 reads (25%) | called by muse, mutect2, varscan2
- C2orf72 | c.*54C>A | 3'UTR (SNP) | VAF 120/312 reads (38%) | called by muse, mutect2, varscan2
- C4orf50 | c.-954C>A | 5'UTR (SNP) | VAF 148/272 reads (54%) | called by mutect2, varscan2
- C6orf118 | c.1303-12C>A | Intron (SNP) | VAF 113/172 reads (66%) | called by muse, mutect2, varscan2
- CCDC120 | c.-56G>T | 5'UTR (SNP) | VAF 490/715 reads (69%) | called by muse, mutect2, varscan2
- CETN3 | c.461-2403G>A | Intron (SNP) | VAF 105/318 reads (33%) | catalogued as rs1433855281; called by muse, mutect2, varscan2
- CLK2P1 | n.765G>C | RNA (SNP) | VAF 322/589 reads (55%) | called by muse, mutect2, varscan2
- CLPSL1 | c.*30C>G | 3'UTR (SNP) | VAF 122/668 reads (18%) | called by muse, mutect2, varscan2
- COL28A1 | c.1998+923G>T | Intron (SNP) | VAF 76/345 reads (22%) | called by muse, mutect2, varscan2
- CORO7 | c.*7C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- DNAJB2 | c.352+94G>T | Intron (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588954 G>T | 5'Flank (SNP) | VAF 158/463 reads (34%) | called by muse, mutect2, varscan2
- DYRK4 | chr12:4588955 G>T | 5'Flank (SNP) | VAF 160/466 reads (34%) | called by muse, mutect2, varscan2
- EYS | c.1767-7304C>T | Intron (SNP) | VAF 166/693 reads (24%) | catalogued as rs775043754, COSV65458754; called by muse, mutect2, varscan2
- FAM193A | c.-219G>C | 5'UTR (SNP) | VAF 79/139 reads (57%) | called by muse, mutect2, varscan2
- FRRS1 | c.1596+13C>G | Intron (SNP) | VAF 69/297 reads (23%) | called by muse, mutect2, varscan2
- GNB1 | c.57+15G>T | Intron (SNP) | VAF 105/210 reads (50%) | called by muse, mutect2, varscan2
- GRM8 | c.727+30272T>C | Intron (SNP) | VAF 112/216 reads (52%) | catalogued as rs910714627; called by muse, mutect2, varscan2
- HLA-DPB1 | c.101-139C>A | Intron (SNP) | VAF 275/521 reads (53%) | called by muse, mutect2, varscan2
- HSP90B1 | c.-21G>C | 5'UTR (SNP) | VAF 76/133 reads (57%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155069223 A>G | 5'Flank (SNP) | VAF 176/403 reads (44%) | catalogued as rs1244816456; called by muse, mutect2, varscan2
- KCNK12 | c.*8509T>C | 3'UTR (SNP) | VAF 137/425 reads (32%) | catalogued as rs1319009941; called by muse, mutect2, varscan2
- LINC00470 | n.1431A>T | RNA (SNP) | VAF 256/487 reads (53%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+660C>G | Intron (SNP) | VAF 236/309 reads (76%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643319 C>G | 5'Flank (SNP) | VAF 60/256 reads (23%) | catalogued as rs765211962; called by muse, mutect2, varscan2
- MFSD10 | c.1252+24G>A | Intron (SNP) | VAF 34/110 reads (31%) | catalogued as rs1470933601; called by muse, mutect2, varscan2
- MGST3 | c.-7-27C>T | Intron (SNP) | VAF 185/496 reads (37%) | catalogued as rs539663851; called by muse, varscan2
- MICU2 | c.598-1189G>C | Intron (SNP) | VAF 124/152 reads (82%) | called by muse, mutect2, varscan2
- MID1 | c.757-5734G>A | Intron (SNP) | VAF 94/456 reads (21%) | called by muse, mutect2, varscan2
- MSR1 | c.1034-528A>T | Intron (SNP) | VAF 78/211 reads (37%) | called by muse, mutect2, varscan2
- NBPF7 | n.176A>T | RNA (SNP) | VAF 193/370 reads (52%) | called by muse, mutect2, varscan2
- NRXN1 | c.3719-1422A>G | Intron (SNP) | VAF 358/760 reads (47%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076330 C>A | 5'Flank (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- OR4C4P | n.833A>C | RNA (SNP) | VAF 20/540 reads (4%) | called by muse, mutect2
- OTOAP1 | n.2475G>T | RNA (SNP) | VAF 126/1012 reads (12%) | called by muse, mutect2, varscan2
- PARGP1 | n.531G>A | RNA (SNP) | VAF 119/647 reads (18%) | called by muse, mutect2, varscan2
- PHGDH | c.1210-48C>T | Intron (SNP) | VAF 16/188 reads (9%) | catalogued as rs763222013; called by muse, mutect2
- PLA2G5 | chr1:20068991 C>A | 5'Flank (SNP) | VAF 140/424 reads (33%) | called by muse, mutect2
- PMEPA1 | chr20:57710414 G>A | 5'Flank (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- PMFBP1 | c.-24G>A | 5'UTR (SNP) | VAF 160/222 reads (72%) | called by muse, mutect2, varscan2
- PPAT | c.403-678A>T | Intron (SNP) | VAF 63/135 reads (47%) | called by muse, mutect2, varscan2
- PPP2R1B | c.*39T>G | 3'UTR (SNP) | VAF 112/280 reads (40%) | called by muse, mutect2, varscan2
- PTHLH | c.-23+49C>G | Intron (SNP) | VAF 124/525 reads (24%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158747 C>A | 5'Flank (SNP) | VAF 96/444 reads (22%) | catalogued as rs112567409; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159510 G>T | 5'Flank (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- RNU6-104P | chr8:43300537 T>A | 5'Flank (SNP) | VAF 170/321 reads (53%) | catalogued as rs1485669521; called by muse, mutect2, varscan2
- SLC1A2 | chr11:35419877 C>A | 5'Flank (SNP) | VAF 70/120 reads (58%) | called by muse, mutect2, varscan2
- TAF4B | c.1832+1703G>T | Intron (SNP) | VAF 51/218 reads (23%) | called by muse, mutect2, varscan2
- TPSD1 | chr16:1262597 G>T | 3'Flank (SNP) | VAF 242/544 reads (44%) | called by muse, mutect2, varscan2
- TRBV23OR9-2 | n.250G>T | RNA (SNP) | VAF 161/533 reads (30%) | called by muse, mutect2, varscan2
- WASF4P | n.1272G>T | RNA (SNP) | VAF 36/172 reads (21%) | called by muse, varscan2
- ZNF134 | c.-146G>T | 5'UTR (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- ZNF849P | n.858C>T | RNA (SNP) | VAF 92/284 reads (32%) | catalogued as rs1258316311; called by muse, mutect2, varscan2
